Gene-level copy-number profile of tumor specimen TCGA-HZ-7289-01A from TCGA case TCGA-HZ-7289, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 77.1 years (28,174 days).
Specimen TCGA-HZ-7289-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.93d6f263-8e1d-4dfb-8871-1c70714fd564.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HZ-7289-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/51a1c0c0-3471-4b79-b5d3-ad805a0cd4f7

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 7,451; copy number 3: 20,136; copy number 4: 22,486; copy number 5: 3,642; copy number 6: 4,759; copy number 7: 551; copy number 9: 149; copy number 11: 278; copy number 13: 52; copy number 16: 142; copy number 17: 59; copy number 21: 40; copy number 28: 52; copy number 32: 7; copy number 41: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HZ-7289-01A-11D-2153-01): tumor purity 0.57, ploidy 3.78, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 793 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:37,133,489–44,115,913, 237 genes, copy number 11–17 (within-gene range 3–17) (broad region; genes not listed).
- chr12:66,767–7,695,775, 239 genes, copy number 13–32 (broad region; genes not listed).
- chr12:22,395,088–33,455,452, 217 genes, copy number 9–41 (broad region; genes not listed).
- chr12:67,929,235–73,208,317, 100 genes, copy number 11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
